Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3601, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3601-01A (Primary Tumor).

Diagnosis/diagnoses:

1. Resected rectosigmoid colon with a deeply ulcerated, extensive, moderately differentiated adenocarcinoma of the colorectal type with widespread infiltration of the perirectal fatty tissue and two local lymph node metastases. In this section the tumor extends to the circumferential resection margin. Tumor-free mesenteric resection margin. Tumor-free colon resection margins.
2. & 3. Both periureteral soft tissue samples with infiltration of the carcinoma described.

Stage of tumor: pT4, pN1 (2/17) pMX; G2, L1, V0, R2

Source: NCI Genomic Data Commons file 35c5f9f5-3463-4b2d-89b6-f7cfaf810e4d (TCGA-AG-3601.B3D3D4F0-4872-4E73-900B-42B0F78CD492.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).